Surgical pathology report (de-identified scan), TCGA case TCGA-77-8156, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8156-01A (Primary Tumor).

[page 1 of 2]
Histopathology Report

HISTORY

Left upper lobectomy. SPN - FNAC - malignant.

MACROSCOPIC

Three specimens submitted:

1: The first specimen is labelled 'left upper lobe lung' and consists of a lobe of lung that measures 150 mm SI, 140 mm AP and 65 mm ML. The hilar margin is inked blue. The specimen has been previously sectioned for research. The pleural surface is slightly haemorrhagic and there is a puckered area measuring 35 x 35 mm on the superior lateral pleural aspect. A bullous is present in the anterior superior aspect of the lung. On sectioning the lung, there is a round tumour with a tan and black cut surface with infiltrating edges in the superior aspect of the lobe that measures 45 mm AP, 30 mm ML and 35 mm SI. The tumour abuts the pleural surface at the previously noted puckering. The tumour is 15 mm from the hilar margin and more than 20 mm from the bronchial resection margin. The remainder of the lung shows marked emphysematous changes. [1A: bronchial resection margin; 1B: 4 lymph nodes; 1C-1E: tumour and pleura; 1F: tumour and adjacent lymph node; 1G: emphysematous lung; 1H: more normal lung inferiorly.]

2: The second specimen is labelled 'left hilar lymph node' and consists of three pieces of tan fibrous tissue, the largest measuring 30 x 18 x 10 mm. All three pieces contain hemorrhagic lymph nodes containing carbon pigment. The largest lymph node measures 25 x 10 x 8 mm. [2A-2B: rep section of each node.]

3: The third specimen is labelled 'mediastinal lymph node' and consists of a single piece of fibrofatty tissue measuring 24 x 14 x 10 mm. The tissue contains a lymph node measuring 9 x 6 x 5 mm. [3A, tissue bisected.]

MICROSCOPIC

1: Sections reveal a poorly differentiated squamous cell carcinoma. Irregular geographic zones of necrosis are present within the tumour. The tumour abuts visceral pleura. No pleural invasion is seen. The tumour is clear of the bronchial resection margin which shows focal mild and moderate squamous dysplasia. No lymphatic or vascular invasion is identified and no perineural permeation by tumour is seen. Peribronchial lymph nodes show reactive changes with follicular hyperplasia, sinus histiocytosis, carbon pigment deposition, and scattered flecks of birefringent material in keeping with silicate. Within immediately adjacent lung parenchyma there is obstructive pneumonitis characterised by endogenous lipid pneumonia. Some follicular lymphoid hyperplasia is also noted. Distant lung parenchyma shows emphysema with subpleural bulla formation. A separate sampled portion of lung shows a usual interstitial pneumonia type reaction pattern characterised by patchy interstitial fibrosis with temporal and spatial heterogeneity. A rare

[page 2 of 2]
Collecte

#REC.: No coll

Histopathology Report

fibroblastic focus is present and there is also some more established fibrosis with muscularisation of stroma and early honeycomb change. Some bronchioloectasis with mucous stasis is also noted within this region.

2&3: Sections of the lymph nodes show reactive changes. No tumour is identified.

SUMMARY

1-3: Left upper lobectomy with separately submitted left hilar lymph node and mediastinal lymph node:

Poorly differentiated squamous cell carcinoma.

Tumour size 45 mm in diameter.

No pleural invasion identified.

Tumour clear of bronchial resection margin (focal mild and moderate squamous dysplasia at margin).

No lymphatic, vascular or perineural invasion present.

Peribronchial lymph nodes and separately submitted left hilar lymph node and mediastinal lymph node not involved by tumour.

Immediately adjacent lung parenchyma shows obstructive pneumonitis.

Pathological stage: pT2a N0.

Emphysema, usual interstitial pneumonia type reaction pattern.

Source: NCI Genomic Data Commons file c2b69a04-d1a8-438b-8d40-2fe57c4d4e3c (TCGA-77-8156.7CE15C6D-0640-47B2-A4CD-0D14F97E6AB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).